Somatic mutation profile of tumor specimen TCGA-GL-A9DC-01A (aliquot TCGA-GL-A9DC-01A-11D-A36X-10) from TCGA case TCGA-GL-A9DC, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.7 years (24,348 days).
Specimen TCGA-GL-A9DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5b97e60-1430-4f45-b146-6081ec526d49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A9DC-10A (Blood Derived Normal), aliquot TCGA-GL-A9DC-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/854ccb00-28bf-4d8f-a6af-38db44c604be

The open-access MAF lists 114 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 23, Frame Shift Del 17, In Frame Del 4, Frame Shift Ins 3, Splice Site 2, RNA 1, Intron 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 133/255 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR19 | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 26/58 reads (45%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- AAR2 | c.868A>C p.K290Q | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV100299423; called by muse, mutect2, varscan2
- ADH6 | c.858C>A p.S286R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99422838; called by muse, mutect2, varscan2
- ALG11 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV101584383; called by muse, mutect2, varscan2
- BCAN | c.1394A>C p.K465T | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.051); catalogued as COSV100228457, COSV61259833; called by muse, mutect2, varscan2
- C4A | c.3088A>C p.K1030Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as COSV101418358; called by mutect2, varscan2
- C5orf49 | c.413A>T p.E138V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100603999; called by muse, mutect2, varscan2
- CADPS | c.3742G>A p.V1248I | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs751860249, COSV99340661; called by muse, mutect2, varscan2
- CALCR | c.1285T>A p.W429R (on ENST00000649521 / NM_001164737.2; = p.W413R on NM_001742.4) | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100810833, COSV64010129; called by muse, mutect2, varscan2
- CAPZA3 | c.383A>C p.Y128S | Missense Mutation (SNP) | VAF 138/229 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99856917; called by muse, mutect2, varscan2
- CNNM3 | c.2043G>C p.K681N | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100562783; called by muse, mutect2, varscan2
- CRAMP1 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99562106; called by muse, mutect2, varscan2
- CSF2RB | c.1932G>T p.Q644H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99454383; called by muse, mutect2, varscan2
- CSMD1 | c.4982A>C p.E1661A (on ENST00000520002; = p.E1660A on NM_033225.6) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100153241; called by muse, mutect2, varscan2
- DDX10 | c.1669T>A p.S557T | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100489908; called by muse, mutect2, varscan2
- DNAH11 | c.3557C>T p.T1186I | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs757753783, COSV100180628; called by muse, mutect2, varscan2
- DOCK4 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.356); catalogued as COSV101455721; called by muse, mutect2, varscan2
- EIF2AK1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99552259; called by muse, mutect2, varscan2
- FAM20A | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1280135042, COSV99873489; called by muse, mutect2, varscan2
- FERMT2 | c.193T>G p.W65G | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100449128; called by muse, mutect2, varscan2
- FNDC3B | c.2374A>T p.S792C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100394874; called by muse, mutect2, varscan2
- FOXD2 | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100599308; called by muse, mutect2
- FOXO1 | c.1355T>C p.M452T | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101092145; called by muse, mutect2, varscan2
- GLYATL1 | c.211T>C p.Y71H (on ENST00000317391 / NM_001354699.1; = p.Y102H on NM_080661.4) | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs772079365, COSV100265535; called by muse, mutect2, varscan2
- GOLT1B | c.262A>T p.I88F | Missense Mutation (SNP) | VAF 99/175 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99982104; called by muse, mutect2, varscan2
- GTF2A2 | c.177+1G>T p.X59_splice | Splice Site (SNP) | VAF 24/80 reads (30%) | catalogued as COSV99139481; called by muse, mutect2, varscan2
- HERC1 | c.10121G>C p.C3374S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101496864; called by muse, mutect2, varscan2
- KCMF1 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV101301279; called by muse, mutect2, varscan2
- KCNH1 | c.1288T>A p.Y430N (on ENST00000271751 / NM_172362.3; = p.Y403N on NM_002238.4) | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99661259; called by muse, mutect2, varscan2
- KDM3A | c.2601T>A p.H867Q | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100460915; called by muse, mutect2, varscan2
- KDM5C | c.4016G>A p.G1339D | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100949444; called by muse, mutect2, varscan2
- KHNYN | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV99250095; called by muse, mutect2, varscan2
- LAMC1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1205645618, COSV99280365; called by muse, mutect2, varscan2
- LGALS3BP | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99431911; called by muse, mutect2, varscan2
- MAGT1 | c.131T>C p.L44P (on ENST00000618282 / NM_001367916.1; = p.L76P on NM_032121.5) | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100800430; called by muse, mutect2, varscan2
- MED13 | c.2718A>C p.E906D | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.97); catalogued as COSV101181348; called by muse, mutect2, varscan2
- MYF6 | c.11A>C p.D4A | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99952931; called by muse, mutect2, varscan2
- NDST1 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99938960, COSV99939066; called by muse, mutect2, varscan2
- PCDHB16 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs139968714; called by muse, mutect2
- PIAS2 | c.1104T>A p.F368L | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100245514; called by muse, mutect2
- PKHD1 | c.9269A>T p.N3090I | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100584444; called by muse, mutect2
- PLEKHH2 | c.3947T>G p.L1316R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99175072; called by muse, mutect2, varscan2
- PLXNC1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99313758; called by muse, mutect2
- POLD1 | c.2438T>A p.L813H | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99570138; called by muse, mutect2, varscan2
- PPP6R1 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV101337012; called by muse, mutect2, varscan2
- PRKAG2 | c.237A>C p.R79S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99835967; called by muse, mutect2, varscan2
- PRKCD | c.1395C>G p.H465Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100388094; called by muse, mutect2, varscan2
- PSTK | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100924793; called by muse, mutect2, varscan2
- RNF168 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100535113; called by muse, mutect2, varscan2
- RRP12 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 165/347 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59668175; called by muse, mutect2, varscan2
- SPEN | c.6088C>T p.P2030S | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV101005558; called by muse, mutect2, varscan2
- SPHK2 | c.1709G>A p.W570* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99709596; called by muse, mutect2, varscan2
- SPIDR | c.2613A>T p.E871D | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99855996; called by muse, mutect2, varscan2
- SREBF2 | c.2039-1G>A p.X680_splice | Splice Site (SNP) | VAF 53/117 reads (45%) | catalogued as COSV100761342, COSV100761545; called by muse, mutect2, varscan2
- SREBF2 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100761520; called by muse, mutect2, varscan2
- TAOK3 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 104/174 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100700389; called by muse, mutect2, varscan2
- TMEM63A | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs770118004, COSV100834445; called by muse, mutect2, varscan2
- TTN | c.44277G>C p.K14759N (on ENST00000591111; = p.K7335N on NM_003319.4) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | PolyPhen probably damaging (0.943); catalogued as COSV100625322, COSV100628170; called by muse, mutect2, varscan2
- WDFY3 | c.10436G>T p.C3479F | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99885462; called by muse, mutect2, varscan2
- WDFY3 | c.10435T>C p.C3479R | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99885465; called by muse, mutect2, varscan2
- WDR41 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV99689122, COSV99689390; called by muse, mutect2, varscan2
- WDR74 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99587051; called by muse, mutect2, varscan2
- WWC3 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755647592, COSV66502195; called by muse, mutect2, varscan2
- ZMPSTE24 | c.58T>A p.F20I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101032097; called by muse, mutect2, varscan2
- ARAP1 | c.3062_3066del p.E1021Afs*4 (on ENST00000393609 / NM_001040118.2; = p.E776Afs*4 on NM_015242.4) | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- BCAS1 | c.1660_1666del p.G554Sfs*101 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- C12orf40 | c.62del p.K21Rfs*9 | Frame Shift Del (DEL) | VAF 38/193 reads (20%) | called by mutect2, pindel, varscan2
- CTDSPL | c.691del p.H231Ifs*15 (on ENST00000273179 / NM_001008392.2; = p.H220Ifs*15 on NM_005808.3) | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- DCST2 | c.357del p.S120Afs*4 | Frame Shift Del (DEL) | VAF 100/251 reads (40%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.92_115del p.Q31_V38del | In Frame Del (DEL) | VAF 37/103 reads (36%) | called by mutect2, pindel, varscan2
- FAM200A | c.788dup p.N263Kfs*7 | Frame Shift Ins (INS) | VAF 53/138 reads (38%) | called by mutect2, pindel, varscan2
- GABRG3 | c.1200del p.F400Lfs*37 | Frame Shift Del (DEL) | VAF 33/159 reads (21%) | called by mutect2, pindel, varscan2
- HRC | c.748_749del p.D250* | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by muse*, mutect2, varscan2*
- NCOA1 | c.1875del p.K625Nfs*9 | Frame Shift Del (DEL) | VAF 72/211 reads (34%) | called by mutect2, pindel, varscan2
- NSMAF | c.1683dup p.Q562Afs*20 | Frame Shift Ins (INS) | VAF 42/119 reads (35%) | called by mutect2, pindel, varscan2
- NUDT16L1 | c.100del p.A34Pfs*18 | Frame Shift Del (DEL) | VAF 70/130 reads (54%) | called by mutect2, pindel*, varscan2
- PRAMEF2 | c.20_28del p.P7_L9del | In Frame Del (DEL) | VAF 85/209 reads (41%) | called by mutect2, pindel, varscan2
- PTPN14 | c.404del p.L135Wfs*4 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- RBM33 | c.1533del p.A512Hfs*138 | Frame Shift Del (DEL) | VAF 68/173 reads (39%) | called by mutect2, pindel, varscan2
- RNF103 | c.438del p.R146Sfs*54 | Frame Shift Del (DEL) | VAF 49/142 reads (35%) | called by mutect2, pindel, varscan2
- SLC12A6 | c.490_497del p.K164* (on ENST00000354181 / NM_001365088.1; = p.K113* on NM_005135.2) | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- SYNCRIP | c.1606_1609del p.R536Vfs*25 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- TASOR | c.1234del p.Y412Ifs*6 (on ENST00000355628 / NM_001365636.2; = p.Y16Ifs*6 on NM_015224.3) | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | called by mutect2, pindel, varscan2
- TRPM6 | c.2511_2516delinsCC p.P838Lfs*64 | Frame Shift Del (DEL) | VAF 65/130 reads (50%) | called by pindel, varscan2*
- VN1R2 | c.922_936del p.S308_R312del | In Frame Del (DEL) | VAF 47/141 reads (33%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.3347del p.D1116Afs*22 | Frame Shift Del (DEL) | VAF 124/333 reads (37%) | called by mutect2, pindel*, varscan2
- ZNF407 | c.4691_4699del p.S1564_P1566del | In Frame Del (DEL) | VAF 82/217 reads (38%) | called by mutect2, pindel, varscan2
- ACSM4 | c.342A>T p.G114= | Silent (SNP) | VAF 154/228 reads (68%) | catalogued as COSV101257338; called by muse, mutect2, varscan2
- ATP2A2 | c.480T>C p.P160= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV100428875; called by muse, mutect2, varscan2
- BICC1 | c.1962T>C p.C654= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99570862; called by muse, mutect2, varscan2
- CEP104 | c.2247T>C p.Y749= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs1475857160, COSV100986724; called by muse, mutect2, varscan2
- DDX25 | c.1317G>C p.G439= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as COSV99700110; called by muse, mutect2, varscan2
- DIRAS1 | c.498G>A p.T166= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1332047021, COSV100053144; called by muse, mutect2, varscan2
- DMWD | c.453C>G p.L151= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV99537395; called by muse, mutect2, varscan2
- GLI2 | c.3417C>G p.A1139= (on ENST00000361492 / NM_001374353.1; = p.A1156= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV100084222; called by muse, mutect2, varscan2
- HOXA11 | c.477C>T p.Y159= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as rs967315565, COSV50053968, COSV50055150; called by muse, mutect2, varscan2
- KLHL38 | c.1356T>C p.Y452= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV100384564; called by muse, mutect2, varscan2
- MST1R | c.2196G>A p.G732= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs775113027, COSV99619573; called by muse, mutect2, varscan2
- OR51S1 | c.612C>T p.A204= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV100437583; called by muse, mutect2, varscan2
- PCDHA12 | c.1233C>T p.S411= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as rs369536692; called by muse, mutect2, varscan2
- PLXNA2 | c.363C>T p.Y121= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV100885850; called by muse, mutect2, varscan2
- SFPQ | c.2061T>A p.T687= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV100599513; called by muse, mutect2, varscan2
- SLC12A7 | c.558C>T p.Y186= | Silent (SNP) | VAF 80/164 reads (49%) | catalogued as rs776038408, COSV99370499; called by muse, mutect2, varscan2
- SLC47A1 | c.1608A>G p.K536= | Silent (SNP) | VAF 118/213 reads (55%) | catalogued as COSV99565628; called by muse, mutect2, varscan2
- SRPRA | c.1407C>A p.T469= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99703047; called by muse, mutect2, varscan2
- TM9SF4 | c.1140C>A p.T380= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV99455112; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1422T>C p.N474= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as rs140339485; called by muse, mutect2, varscan2
- USP47 | c.741A>G p.K247= (on ENST00000399455 / NM_001372095.1; = p.K159= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 242/568 reads (43%) | catalogued as COSV100359934; called by muse, mutect2, varscan2
- ZNF331 | c.1110C>T p.L370= | Silent (SNP) | VAF 105/234 reads (45%) | catalogued as COSV99467887; called by muse, mutect2, varscan2
- ZNF823 | c.564A>C p.G188= (on ENST00000341191 / NM_001297610.2; = p.G144= on NM_017507.2) | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as COSV100362628; called by muse, mutect2, varscan2
- CD300E | c.*2G>A | 3'UTR (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100151431; called by muse, mutect2, varscan2
- ELP5 | c.735+45A>G | Intron (SNP) | VAF 92/170 reads (54%) | catalogued as COSV100598239; called by muse, mutect2, varscan2
- LINC02694 | n.12T>C | RNA (SNP) | VAF 53/112 reads (47%) | catalogued as rs778481261, COSV100601940; called by muse, mutect2, varscan2
